MMRF case MMRF_2493 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/12d3a070-42a0-4de5-a684-ffae512109a4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.0 years (25,184 days); ISS stage: III; Days to last known disease status: 695 days (1.9 years); Days to last follow up: 695 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 16 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 6 days; Days to treatment end: 16 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 36 days; Days to treatment end: 258 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 36 days.
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 482 days (1.3 years); Days to treatment end: 573 days (1.6 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: First line of therapy; Days to treatment start: 587 days (1.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1095 mg/dL; Immunoglobulin G 9.85 g/L; Beta 2 Microglobulin 6.19 µg/mL; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 132 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 5.39 mmol/L.
- Day 105 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 16.1 mg/dL; Immunoglobulin G 6.02 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 5.7 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 137 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 33 g/L; Total Protein 5.6 g/dL; Glucose 6.88 mmol/L.
- Day 175 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.31 mg/dL; Immunoglobulin G 5.27 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 5.78 mmol/L.
- Day 258 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.44 mg/dL; Immunoglobulin G 8.74 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 155 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 5.72 mmol/L.
- Day 343 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.55 mg/dL; Immunoglobulin G 0.98 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 6.05 mmol/L.
- Day 510 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.79 mg/dL; Immunoglobulin G 7.61 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.18 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 164 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.61 mmol/L.
- Day 581 (ECOG 0): Hemoglobin 7.01 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.13 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.23 mmol/L.
- Day 695: Hemoglobin 7.01 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5.72 ×10⁹/L; Platelets 151 ×10⁹/L.

Other clinical attributes
- Day -6: Weight: 120 kg; Height: 180 cm.

Biospecimens (2 samples)
- Sample MMRF_2493_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2493_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
